Somatic mutation profile of tumor specimen 0DFRTR from CCDI case PBBRYS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (328 days).
Specimen 0DFRTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70835458-bac2-49a3-81e4-67cc83f29feb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRTS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dda2fbe5-605a-455d-b6be-3cff949f3860

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, 5'UTR 1, Splice Region 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRC9 | c.3853C>T p.R1285* | Nonsense Mutation (SNP) | VAF 66/903 reads (7%) | catalogued as rs1467701623; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 56/1201 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 34/976 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- MIS18BP1 | c.3295+8A>G | Splice Region (SNP) | VAF 36/754 reads (5%) | called by muse, mutect2
- DMP1 | c.1032C>A p.A344= | Silent (SNP) | VAF 54/1207 reads (4%) | called by muse, mutect2
- TBCCD1 | c.210C>T p.D70= | Silent (SNP) | VAF 86/1158 reads (7%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/258 reads (12%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 18/614 reads (3%) | called by muse, mutect2
